TCGA case TCGA-DA-A1HY — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: Yale. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/40e17bf8-6c19-4e5e-b60d-ad54f504a970

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: Progression; Age at diagnosis: 47.5 years (17,367 days); Days to diagnosis: 2,010 days (5.5 years); Prior treatment: No; Days to last follow up: 4,407 days (12.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 42.0 years (15,357 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 3,199 days (8.8 years); Disease response: Tumor Free.
- Days to follow up: 3,580 days (9.8 years); Disease response: Tumor Free.
- Days to follow up: 3,950 days (10.8 years); Disease response: Tumor Free.
- Days to follow up: 4,407 days (12.1 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 178 cm; BMI: 25.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DA-A1HY-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DA-A1HY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-DA-A1HY-06A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DA-A1HY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 1.13; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,407 days; disease-specific survival: no event (censored), 4,407 days; progression-free interval: no event (censored), 4,407 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DA-A1HY-06A-11D-A192-01): tumor purity 0.76, ploidy 2, whole-genome doublings 0.
